Somatic mutation profile of tumor specimen MP2PRT-PAVXPP-TMP1-A (aliquot MP2PRT-PAVXPP-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVXPP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (684 days).
Specimen MP2PRT-PAVXPP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3218365c-1ba6-4e09-a7a8-62f2263f5778.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXPP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXPP-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84b51f28-2490-47a6-b0fe-0bfa8a935520

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH1A2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 116/497 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs137957671; called by muse, mutect2
- CFHR2 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs778532035; called by muse, mutect2, varscan2
- CMKLR1 | c.410G>A p.R137H (on ENST00000312143 / NM_001142344.2; = p.R135H on NM_004072.3) | Missense Mutation (SNP) | VAF 60/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201652470, COSV56439427; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs866644199, COSV54742922, COSV99600060; called by muse, mutect2
- FUT3 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 84/673 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs543564207; called by muse, mutect2, varscan2
- KLHL13 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV53247842; called by muse, mutect2, varscan2
- RNF157 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 50/270 reads (19%) | catalogued as rs1334675924, COSV99487002; called by muse, mutect2, varscan2
- TRDN | c.1063del p.A355Lfs*9 | Frame Shift Del (DEL) | VAF 36/320 reads (11%) | catalogued as COSV100521683, COSV62122881; called by mutect2, pindel, varscan2
- HDAC2 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.7645A>T p.S2549C | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AC109583.1 | c.-542-13812G>A | Intron (SNP) | VAF 48/309 reads (16%) | catalogued as rs904381507; called by muse, mutect2, varscan2
- IGKV5-2 | chr2:88897784 ins CTTTCTGC | 3'Flank (INS) | VAF 14/110 reads (13%) | called by mutect2, pindel
- KCTD1 | c.-15-45551T>C | Intron (SNP) | VAF 42/488 reads (9%) | called by muse, mutect2
